CCG case CUPP-B493 — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/10fb3d9a-8317-46e1-98e0-6c34d30da665

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1953; Vital status: Dead; Days to death: -1 day; Year of death: 2013; Cause of death: Cancer Related.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 59.3 years (21,646 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC clinical T: T4; AJCC clinical N: N2; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic T: T4; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Sites of involvement: Bone, NOS / Liver / Omentum / Diaphragm / Ovary, NOS / Peritoneum, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Neoadjuvant; Initial disease status: Initial Diagnosis; Timepoint category: Preoperative.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (2 entries)
- Days to follow up: -1 day; Disease response: With Tumor.
- Day 0 (initial diagnosis): Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 84.1 kg.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B493-NT1-A: Sample type: FFPE Scrolls; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B493-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample CUPP-B493-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B493-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 13; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
